Gene-level copy-number profile of tumor specimen TCGA-2G-AAG1-01A from TCGA case TCGA-2G-AAG1, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed germ cell tumor; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 28.4 years (10,359 days).
Specimen TCGA-2G-AAG1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f6921584-57c2-4c6c-9da9-85f50e28d163.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-2G-AAG1-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/a4119d2c-7b0a-4671-af74-f0fe89a7fb46

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 28; copy number 1: 3,082; copy number 2: 33,531; copy number 3: 19,065; copy number 4: 1,602; copy number 5: 332; copy number 6: 206; copy number 7: 205; copy number 8: 731; copy number 9: 123.

Homozygous deletions (total copy number 0; autosomes only): 28 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–143,450,245, 3 genes: AC239859.5, RNA5SP533, AC239859.3.
- chr9:137,086,985–137,109,183, 2 genes: MAN1B1, SNORD62.
- chr16:16,290,135–16,398,594, 15 genes (within-gene range 0–2): AC136624.2, MIR3179-2, MIR3670-2, AC138969.2, MIR3180-2, PKD1P1, Y_RNA, AC138969.1, MIR6511A2, MIR6770-2, AC138969.3, PKD1P2, MIR6511A3, NPIPA7, AC136619.1.
- chr16:16,541,217–16,541,847, 1 gene: AC136619.2.
- chr16:29,442,917–29,613,717, 1 gene (within-gene range 0–2): AC133555.6.
- chr16:29,527,568–29,636,328, 6 genes: SMG1P2, AC009086.2, MIR3680-2, SLC7A5P1, CA5AP1, AC009086.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,597 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:52,872,982–53,366,066, 1 gene, copy number 5 (within-gene range 3–5): SCFD2.
- chr4:53,265,461–68,497,604, 193 genes, copy number 5–9 (broad region; genes not listed).
- chr4:68,704,600–76,898,144, 179 genes, copy number 6–7 (broad region; genes not listed).
- chr8:51,961,458–52,745,843, 10 genes, copy number 5: AC064807.2, AC064807.3, ST18, AC021915.2, AC021915.1, AC103831.1, RPL34P17, ALKAL1, RB1CC1, AC113139.1.
- chr11:18,836,304–18,939,721, 7 genes, copy number 5: MRGPRX8P, MRGPRX7P, AC023078.2, MRGPRX6P, MRGPRX5P, MRGPRX1, AC023078.1.
- chr11:30,167,163–30,167,306, 1 gene, copy number 5: AL358944.2.
- chr12:66,767–34,249,958, 831 genes, copy number 8–9 (broad region; genes not listed).
- chr12:38,906,451–44,389,762, 70 genes, copy number 6–7 (within-gene range 3–7) (broad region; genes not listed).
- chr18:23,197,144–27,595,164, 81 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr18:48,919,853–49,048,474, 4 genes, copy number 5 (within-gene range 4–5): SMAD7, AC114684.1, AC016866.3, AC016866.1.
- chr20:31,257,664–31,311,962, 5 genes, copy number 5: DEFB115, DKKL1P1, AL121723.1, DEFB116, RPL31P3.
- chr22:17,787,649–18,024,561, 1 gene, copy number 5 (within-gene range 3–5): MICAL3.
- chr22:17,980,868–18,947,741, 46 genes, copy number 5: MIR648, AC016027.3, AC016027.2, RHEBP3, LINC01634, AC016027.1, PEX26, AC016027.5, AC016027.4, ARL2BPP10, TUBA8, AC008079.1, USP18, FAM230D, GGTLC5P, FAM230J, AC011718.1, PPP1R26P3, FAM230A, AC023490.2, FAM247B, GGTLC3, Metazoa_SRP, AC023490.3, TMEM191B, PI4KAP1, AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2, CA15P2, PPP1R26P2, PPP1R26P4, FAM230E, GGT3P, AC008132.2, E2F6P1, AC008132.1, BCRP7, FAM230F, AC008103.1, DGCR6, AC007326.4, PRODH, AC007326.5.
- chr22:21,370,064–21,396,590, 6 genes, copy number 5: AP000552.1, Metazoa_SRP, RIMBP3B, RN7SKP63, AP000552.3, Metazoa_SRP.
- chr22:21,544,897–23,008,356, 162 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 226. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
